Gene-level copy-number profile of tumor specimen TCGA-W5-AA2M-01A from TCGA case TCGA-W5-AA2M, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 49.3 years (17,989 days).
Specimen TCGA-W5-AA2M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a702a89d-9416-477e-8943-6787854575df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-W5-AA2M-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/58f3d078-1cdc-4b2b-8f61-cce4d02ac6c3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 593; copy number 2: 14,071; copy number 3: 6,464; copy number 4: 32,036; copy number 5: 5,179; copy number 6: 247; copy number 7: 2; copy number 8: 17; copy number 9: 35; copy number 10: 143; copy number 11: 4; copy number 12: 59; copy number 13: 19; copy number 17: 7; copy number 19: 18; copy number 20: 15.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–22,029,594, 48 genes (within-gene range 0–2): HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene (within-gene range 0–2): AL449423.1.
- chr9:26,642,697–28,670,286, 30 genes (within-gene range 0–2): AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1.
- chr12:116,368,764–116,428,318, 2 genes: AC079384.1, MIR4472-2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 300 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,396,659–39,487,177, 19 genes, copy number 10 (within-gene range 8–10): RNU6-753P, LINC01685, HSPA5P1, RRAGC, AL139260.2, AL139260.1, MYCBP, AL139260.3, GJA9, RHBDL2, RNU6-605P, Y_RNA, EIF1P2, AKIRIN1, NDUFS5, MACF1, RNU6-608P, RNA5SP44, AL442071.2.
- chr1:39,491,636–39,576,790, 6 genes, copy number 10: BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55.
- chr1:40,493,157–41,484,683, 34 genes, copy number 9–20 (within-gene range 6–20): AL603839.3, EXO5, AL603839.1, AL603839.2, ZNF684, AL356379.2, AL356379.1, GTF2F2P2, RIMS3, AL031289.2, AL031289.1, NFYC-AS1, NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4, AC119677.1, AL391730.1, AL391730.2, UBE2V1P8, CTPS1, SLFNL1-AS1, SLFNL1, SCMH1, RPL23AP17, AC093151.7, AC093151.2, AC093151.1, FOXO6, FOXO6-AS1, RNA5SP45, EDN2.
- chr1:42,036,143–46,036,122, 153 genes, copy number 9–12 (broad region; genes not listed).
- chr7:34,297,496–36,841,373, 47 genes, copy number 10–12: RNU6-438P, NPSR1-AS1, NPSR1, RPL7P31, NCAPD2P1, RN7SL132P, AC004788.1, DPY19L1, MIR548N, AC005400.1, DPY19L2P1, S100A11P2, TBX20, AC009531.1, AC007652.1, HERPUD2, AC018647.2, AC018647.1, SEPTIN7-DT, AC007551.1, SEPTIN7, AC007551.2, RNU6-1085P, AC087072.1, SEPTIN7P3, PPP1R14BP4, AC083864.2, AC083864.1, AC083864.3, MARK2P13, AC078841.1, EEPD1, AC007327.1, AC007327.2, AC006960.1, AC006960.3, KIAA0895, Y_RNA, ANLN, AC006960.2, AOAH, AOAH-IT1, AC007349.4, AC007349.1, AC007349.3, NPM1P18, AC007349.2.
- chr11:69,048,932–70,436,584, 41 genes, copy number 11–19: TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
